Gene-level copy-number profile of tumor specimen MP2PRT-PAPXIK-TMP1-A from MP2PRT case MP2PRT-PAPXIK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.5 years (4,218 days).
Specimen MP2PRT-PAPXIK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b4615c50-dba5-43ea-836c-10a52de25eb8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPXIK-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/5945d4c6-06b4-4158-9eed-7a02e75367c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 158; copy number 1: 86; copy number 2: 33,452; copy number 3: 22,748; copy number 4: 1,931; copy number 5: 11; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 158 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,078,010–89,100,361, 3 genes (within-gene range 0–1): IGKV2-14, IGKV3-15, IGKV1-16.
- chr7:38,257,879–38,311,808, 8 genes (within-gene range 0–1): TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:22,438,547–22,487,245, 20 genes (within-gene range 0–3): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–3) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr14:106,586,376–106,627,825, 9 genes (within-gene range 0–1): IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:145,047,860–145,066,685, 2 genes, copy number 5: AC139103.1, C8orf33.
- chr18:45,034–88,570, 4 genes, copy number 5: AP001005.1, TUBB8B, AP001005.3, IL9RP4.
- chr18:80,109,262–80,247,514, 5 genes, copy number 5: ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr21:46,635,595–46,691,226, 3 genes, copy number 6: PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 86. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
